Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8I8, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8I8-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT OBTURATOR LYMPH NODES:
Four lymph nodes, no tumor present. (0/4)
- (B) LEFT HYPOGASTRIC LYMPH NODES:
Three lymph nodes, no tumor present. (0/3)
- (C) RIGHT OBTURATOR LYMPH NODES:
Seven lymph nodes, no tumor present. (0/7)
- (D) RIGHT HYPOGASTRIC LYMPH NODES:
Thirteen lymph nodes, no tumor present. (0/13)
- (E) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

CLC ICD O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 11/24/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) LEFT OBTURATOR LYMPH NODES – Received is a fibroadipose tissue fragment (5.5 x 4.5 x 1.0 cm), from which four possible lymph nodes are identified, ranging in size from (0.5 x 0.5 x 0.5 cm to 3.5 x 1.5 x 0.8 cm).
SECTION CODE: A1, A2, one lymph node, serially sectioned; A4, one lymph node, bisected; A5, two lymph nodes.
- (B) LEFT HYPOGASTRIC LYMPH NODES – Received is a (4.5 x 3.0 x 1.0 cm) fragment of fibroadipose tissue from which two possible lymph nodes are identified, ranging in size from (0.5 x 0.5 x 0.5 cm to 1.5 x 0.5 x 0.5 cm).
SECTION CODE: B1, one lymph node; B2, one lymph node; B3, B4, remaining fat, entirely submitted.
- (C) RIGHT OBTURATOR LYMPH NODES – Received is a (4.0 x 3.5 x 1.2 cm) fragment of adipose tissue from which seven possible lymph nodes are identified ranging in size from (0.3 x 0.3 x 0.3 cm to 3.5 x 1.0 x 1.0 cm).
SECTION CODE: C1, five possible lymph nodes; C2, one lymph node, serially sectioned; C3-C5, one lymph node, serially sectioned.
- (D) RIGHT HYPOGASTRIC LYMPH NODES – A (5.5 x 5.0 x 1.2 cm) aggregate of fibroadipose tissue. The tissue is dissected to reveal fourteen possible lymph nodes, ranging from (0.1 x 0.1 x 0.1 cm – 1.1 x 1.0 x 0.5 cm).
SECTION CODE: D1-D4, three possible lymph nodes in each; D5, two possible lymph nodes.
- (E) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

T-C4600, M-00110

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 4]
[REDACTED]

Specimen Date/Time:

[page 3 of 4]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(E) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5). (SEE COMMENT).

TUMOR EXTENDING INTO EXTRAPROSTATIC TISSUE.

TUMOR INVADING RIGHT AND LEFT SEMINAL VESICLES AND PERIVESICULAR SOFT TISSUE.

TUMOR EXTENDING TO THE CAUTERIZED MARGIN OF RESECTION.

LYMPHOVASCULAR AND PERINEURAL INVASION PRESENT.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma. Both tumor foci are located in the peripheral zone. The dominant tumor focus is located in the left lateral, left posterolateral, left posterior, mid-posterior, right posterior, right posterolateral and right lateral peripheral zone. This tumor focus measures 3.8 x 1.8 cm in largest cross-sectional dimension and it is present in the two cross-sections of the prostate and extensively in the apex and base. The tumor exhibits extraprostatic extension on the left posterolateral surface of the prostate and right and left superior neurovascular bundle regions. The tumor extends to the right bladder neck margin of resection. The area of the positive margin is cauterized and the added length of the cauterized margin on the right base is 4.0 mm. The second tumor focus is located in the right anterolateral and right lateral peripheral zone. This tumor focus measures less than 0.1 x less than 0.1 cm in largest cross-sectional dimension and it is present in the first cross-section and focally in the apex. The non-dominant tumor focus is of lower histologic grade and confined to the prostate with negative margins.

GROSS DESCRIPTION

(E) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.0 x 2.5 x 4.0 cm, 28.0 grams, post-fixation) has the usual shape. The soft tissue present along the left posterolateral aspect of the prostate appears more abundant than along the right side. A palpable nodule is present on the left mid and base regions of the prostate. Serial cross-sections after fixation demonstrate an area consistent with tumor in the right and left sides of the two cross-sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: E1-E2, base of right seminal vesicle and right vas deferens; E3-E4, base of left seminal vesicle and left vas deferens; E5, prostatic base, right border; E6-E8, prostatic base, right posterior border; E9-E16, prostatic base, central portion; E17, prostatic base, left border; E18-E21, prostatic base, left posterior border; E22-E23, apex anterior; E24-E25, apex left;

[page 4 of 4]
Specimen Date/Time:

E26-E27, apex posterior; E28-E29, apex right; E30-E37, sections of the two cross-sections of the prostate according to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 026244ba-932b-4de0-aff9-7b3cbe15619e (TCGA-KK-A8I8.EA62695C-65BD-4E4A-BB9D-0D1CC5B90636.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).